Somatic mutation profile of tumor specimen 0DKIIF from CCDI case PBBYHE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.5 years (2,733 days).
Specimen 0DKIIF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f58675e0-60e7-4c30-b1a8-99f76f1077c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKIHT (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b26aeff-8e99-4893-9ef1-91a7e22afe0a

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TJP1 | c.925C>T p.R309C | Missense Mutation (SNP) | VAF 166/333 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.639); catalogued as rs775183311, COSV62042960; called by muse, mutect2, varscan2
- XIRP2 | c.7250C>A p.T2417N (on ENST00000628543; = p.T2592N on NM_152381.6) | Missense Mutation (SNP) | VAF 283/610 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs751223636, COSV99744023; called by muse, mutect2, varscan2
- IGSF8 | c.166G>A p.G56S | Missense Mutation (SNP) | VAF 153/355 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ESPNL | c.1917C>T p.S639= | Silent (SNP) | VAF 101/218 reads (46%) | catalogued as rs1191143428; called by muse, mutect2, varscan2
- OR5M8 | c.669T>C p.A223= | Silent (SNP) | VAF 242/556 reads (44%) | called by muse, mutect2, varscan2
- TEX12 | c.-83T>C | 5'UTR (SNP) | VAF 74/363 reads (20%) | called by muse, mutect2, varscan2
